TARGET case TARGET-40-NAAGJY — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5a1bfb37-526f-5375-bcde-83ea55e40b6a

Demographics
Sex at birth: male; Race: asian; Age at index: 10 years; Vital status: Dead; Days to death: 445 days (1.2 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 10.7 years (3,922 days); Year of diagnosis: 2012; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 445 days (1.2 years); Sites of involvement: Bone, NOS.
   Pathology details: Necrosis percent: 70.

Follow-up (2 entries)
- Days to follow up: 174 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 174 days; Days to first event: 174 days; First event: Relapse.
- Days to follow up: 445 days (1.2 years); Year of follow up: 2013.

Biospecimens (3 samples)
- Sample TARGET-40-NAAGJY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAGJY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-40-NAAGJY-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGJY-01A-01D:
- Specimen Type: tumor DNA
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 70
- % Non Tumor Nuclei: Top from Biopsy: 30
- % Cellular Tumor: Top from Biopsy: 40
- % Normal: Top from Biopsy: 60
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 0

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 445
- Protocol: Other osteosarcoma
- Disease at diagnosis: Metastatic
- Metastasis site: Bone only
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Other bone
- Time to first enrollment on relapse protocol in days: 194
